TARGET case TARGET-30-PAIPGU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/68779778-b56c-5cb0-9eef-03945dddc402

Demographics
Sex at birth: female; Race: white; Age at index: 2 years; Vital status: Dead; Days to death: 436 days (1.2 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 2.5 years (898 days); Year of diagnosis: 1998; Days to last follow up: 436 days (1.2 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: 9047.

Follow-up (1 entry)
- Days to follow up: 436 days (1.2 years); Days to first event: 436 days (1.2 years); First event: Death; Year of follow up: 1999.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIPGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIPGU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 436
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.04
- Percent Tumor v/s Stroma: 95/5
